CCDI case PBBYTS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/65c15124-323a-4629-9b7f-4a119cc0e5b1

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 3.2 years (1,155 days).

Biospecimens (3 samples)
- Sample 0DKSTX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKSVT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKSWT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
